Surgical pathology report (de-identified scan), TCGA case TCGA-56-8309, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8309-01A (Primary Tumor).

[page 1 of 3]
Pre-Op Diagnosis
Lung nodule
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Three parts

Container labeled "[REDACTED] - right lung lower lobe" has a previously sectioned moderately distorted recognizable portion of pulmonary parenchyma weighing as received 249 grams and measuring on reconstruction approximately 13.8 x 8.5 x 4.7 cm. This appears grossly consistent with right lower lobe. The specimen is received after tissue harvest for genomic study. Within the specimen container are three tissue cassettes labeled "[REDACTED]". The margins of resection are several apparent staple lines which close off vascular and bronchial structures. The pleura is mottled gray-pink to brown. Noted on the superior anterior aspect is a previously sectioned apparent lobulated partially cystic nodular lesion measuring on reconstruction approximately 2.3 x 2.0 x 1.8 cm. This grossly appears to have extended to the pleura but not grossly through it. This has a gritty friable gray-tan cut surface. This is noted at its nearest point approximately 3.0 cm from the nearest bronchial margin. An apparent small bronchial connection is identified. The remaining parenchyma is spongy and red-brown with areas of congestion and focal anthracotic streaking. Noted near the base on the lateral aspect is a 0.3 cm gray-white fibrotic plaque on the pleura. Representative sections are submitted labeled as follows: A - apparent shaved bronchial margins; B-G - entire remaining lesion and surrounding tissue; H - pleural plaque; I - random grossly uninvolved parenchyma.

[page 2 of 3]
Container labeled [REDACTED] - level 4 lymph node" has 1.0 x 0.8 x 0.4 cm of gray-tan to yellow fleshy and fatty tissue fragments which are entirely submitted in a single cassette.

Container labeled "[REDACTED] - level 9 lymph node" has a 0.7 x 0.6 x 0.3 cm irregular fragment of gray-tan to brown tissue with a few staples in place. The specimen is entirely submitted in a single cassette.

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Lung, right lower lobe (lobectomy):

Specimen integrity: Intact.

Specimen laterality: Right.

Tumor site: Right lower lobe.

Tumor size: 2.3 cm in greatest diameter.

Tumor focality: Unifocal.

Histologic type: Large cell carcinoma consistent with squamous cell carcinoma (see comment).

Grade: Grade III, poorly differentiated.

Visceral pleural invasion: Carcinoma extends up to but not into visceral pleura as confirmed on elastic stain (see comment).

Tumor extension: Not applicable.

Margin status:

Bronchial margin: No carcinoma identified.

Vascular margin: No carcinoma identified.

Parenchymal margin: Not applicable.

Visceral pleural margin: No carcinoma identified.

Distance of invasive carcinoma from closest margin: 1 mm from the visceral pleural margin.

Treatment effect: Unknown.

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified.

Other findings:

Fibrous pleural plaque. [REDACTED]

Emphysematous changes. [REDACTED]

Focal mild interstitial chronic inflammation. [REDACTED]

Focal acute inflammation of the lung pleura with recent hemorrhage and focal fibrosis with cautery artifact.

Lymph node, level 4 (biopsy):

Small fragments of lymph node demonstrating reactive sinus histiocytosis, mild lymphoid hyperplasia, and anthrasilicosis, no metastatic carcinoma identified (see comment). [REDACTED]

Level 9 lymph node (biopsy):

Benign pulmonary parenchyma and recent hemorrhage, no lymph node identified. [REDACTED]

SPC-A

Stage: pT1bN0 (see comment)

Comments

Sections show a poorly differentiated large cell carcinoma. No glandular differentiation and no keratinization is identified.

[page 3 of 3]
Focally, a suggestion of intercellular bridges is identified. A mucin stain is performed which demonstrates no mucin positivity (appropriate positive control). A CK5/6, CK7, TTF1, and p63 stain are performed (appropriate positive and negative controls). The neoplastic cells are strongly positive for CK5/6 and p63. The neoplastic cells are focally positive for CK7 and negative for TTF1.

In summary, the immunohistochemical stains in combination with the mucin and the morphology are consistent with a poorly differentiated squamous cell carcinoma. The neoplasm extends up to the viscera pleura. An elastic stain is performed (appropriate positive control). This confirms that the carcinoma extends up to but not into the viscera pleura. Along the pleural surface are some polymorphonuclear leukocytes, acute inflammation. The level 4 lymph nodes were received fragmented and an accurate node count cannot be performed. The level 9 lymph nodes consisted of benign pulmonary parenchyma and recent hemorrhage. No lymph node was present.

This is staged as a pT1b based on a size of 2.3 cm. This is also stated as a pN0 although it must be noted that only the level 4 lymph nodes were sampled. Clinical correlation and follow up is recommended.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This test has been finalized at the [REDACTED] Campus.

This test was developed and its performance characteristics determined by [REDACTED] Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

<Sign Out Dr. Signature>

Source: NCI Genomic Data Commons file 891c730b-21d5-449c-8970-2ea188eeccda (TCGA-56-8309.A01BEC0A-8ECC-40CD-9B25-885F31390ED8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).